MMRF case MMRF_1110 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5e575a03-c342-4719-8224-61d7276b0fcd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.6 years (25,408 days); ISS stage: III; Days to last known disease status: 1,758 days (4.8 years); Days to last follow up: 1,758 days (4.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 96 days; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 204 days; Days to treatment end: 344 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 371 days (1.0 years); Days to treatment end: 671 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 712 days (1.9 years); Days to treatment end: 876 days (2.4 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,331 days (3.6 years); Days to treatment end: 1,496 days (4.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,331 days (3.6 years); Days to treatment end: 1,387 days (3.8 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,501 days (4.1 years); Days to treatment end: 1,501 days (4.1 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,503 days (4.1 years); Days to treatment end: 1,503 days (4.1 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,635 days (4.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -41: M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 149 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 26.5 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 9 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 10.6 g/dL; Glucose 4.73 mmol/L.
- Day 51: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.236 g/L; Beta 2 Microglobulin 4.4 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 8.09 mmol/L.
- Day 191: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 2.19 g/L; Immunoglobulin M 2.18 g/L; Beta 2 Microglobulin 4.2 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 4.79 mmol/L.
- Day 264 (ECOG 2): Hemoglobin 5.77 mmol/L; Leukocytes 6 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 6.22 mmol/L.
- Day 344: Hemoglobin 5.15 mmol/L; Leukocytes 0.5 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.78 mmol/L.
- Day 442: Hemoglobin 6.32 mmol/L; Leukocytes 4.08 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 6.49 mmol/L.
- Day 523: Hemoglobin 6.88 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 589: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.2 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 3.44 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 3.49 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 6.22 mmol/L.
- Day 698: Serum Free Immunoglobulin Light Chain, Kappa 7.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 2.21 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 6.98 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 7.39 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 782 (ECOG 1): Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.81 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 7.43 mmol/L.
- Day 866 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 4.15 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 5.52 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 6.71 mmol/L.
- Day 974 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.4 mg/dL; Beta 2 Microglobulin 4.5 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 5.9 ×10⁹/L; Platelets 223 ×10⁹/L.
- Day 1,072 (ECOG 1): Hemoglobin 6.88 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 8.4 ×10⁹/L; Platelets 347 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 8.2 mmol/L.
- Day 1,156 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 4.27 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 6.99 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.86 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 7.7 mmol/L.
- Day 1,219 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 13.8 g/L; Beta 2 Microglobulin 4.2 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 6 ×10⁹/L; Platelets 226 ×10⁹/L.
- Day 1,289 (ECOG 2): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 185 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 25.3 g/L; Immunoglobulin A 0.586 g/L; Immunoglobulin M 0.257 g/L; Beta 2 Microglobulin 8.5 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 8.8 g/dL; Glucose 6.71 mmol/L.
- Day 1,359 (ECOG 1): Hemoglobin 6.08 mmol/L; Leukocytes 6 ×10⁹/L; Platelets 171 ×10⁹/L.
- Day 1,482: M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.36 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 4.68 mmol/L.
- Day 1,549 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 8.42 mmol/L.
- Day 1,702 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 83.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 8.09 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 5.41 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 4.5 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 4.62 mmol/L.
- Day 1,758 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 84.6 mg/dL; Immunoglobulin G 22 g/L; Beta 2 Microglobulin 7.86 µg/mL; Hemoglobin 5.58 mmol/L; Leukocytes 3.4 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 186 µmol/L.

Other clinical attributes
- Day -41: Weight: 71 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1110_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,289 days (3.5 years).
- Sample MMRF_1110_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1,289 days (3.5 years).
